Somatic mutation profile of tumor specimen MMRF_1639_3_BM_CD138pos (aliquot MMRF_1639_3_BM_CD138pos_T1_KHS5U_L11631) from MMRF case MMRF_1639, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,581 days).
Specimen MMRF_1639_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b41334b-3eb2-4a46-9f68-883f37d1369a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1639_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1639_1_PB_Whole_C3_KBS5U_L04320; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7ba61a-3c4e-41b8-a8f4-f48dc1b4aa5b

The open-access MAF lists 132 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 31, Intron 20, Silent 17, Nonsense Mutation 6, 5'UTR 6, Splice Site 4, Splice Region 2, RNA 2, 3'Flank 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 65/121 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- BMERB1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs202088138, COSV55508280; called by muse, mutect2, varscan2
- C14orf93 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 131/190 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs143379381; called by muse, mutect2, varscan2
- CDH12 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 151/458 reads (33%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV66426630; called by muse, mutect2, varscan2
- CDH7 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs562336351; called by muse, mutect2, varscan2
- CDH8 | c.1536+6T>G | Splice Region (SNP) | VAF 79/172 reads (46%) | catalogued as COSV54848692; called by muse, mutect2, varscan2
- COL6A5 | c.6898C>T p.Q2300* (on ENST00000312481; = p.Q2296* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV99592223; called by muse, mutect2, varscan2
- CR1 | c.401+6T>C | Splice Region (SNP) | VAF 75/168 reads (45%) | catalogued as rs187655279; called by muse, mutect2, varscan2
- FAM187B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1389739363; called by muse, mutect2, varscan2
- FOXRED1 | c.1241A>C p.N414T | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200742305; called by muse, mutect2, varscan2
- GK | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV66735438; called by muse, mutect2
- HEPACAM2 | c.364G>A p.V122M (on ENST00000394468 / NM_001039372.4; = p.V110M on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139218067; called by muse, mutect2, varscan2
- IGHV1-69D | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 158/478 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs1283966798; called by muse, varscan2
- IGHV2-70D | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 111/334 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1169792576; called by muse, varscan2
- IGLV3-1 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs369317662; called by muse, mutect2, varscan2
- LAMB1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs200303288; called by muse, mutect2, varscan2
- MAP3K1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.644); catalogued as rs763984353; called by muse, mutect2, varscan2
- OSCP1 | c.955C>T p.R319W (on ENST00000356637 / NM_001330493.1; = p.R309W on NM_145047.5) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406005863; called by muse, mutect2, varscan2
- RAD9B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1439336615, COSV63778564; called by muse, mutect2, varscan2
- RB1 | c.1696-1G>T p.X566_splice | Splice Site (SNP) | VAF 27/32 reads (84%) | catalogued as CS951523, COSV57329272; called by muse, mutect2, varscan2
- RFX2 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1015514275; called by muse, mutect2, varscan2
- RHOU | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 121/245 reads (49%) | catalogued as rs745690593; called by muse, mutect2, varscan2
- SCN9A | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1060502050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A9 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as rs747080169; called by muse, mutect2, varscan2
- SPRED1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.758); catalogued as COSV54434997; called by muse, mutect2, varscan2
- BDP1 | c.6995+1G>A p.X2332_splice | Splice Site (SNP) | VAF 81/332 reads (24%) | called by muse, mutect2, varscan2
- BRDT | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- BRWD3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- C17orf80 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CLCN1 | c.1850C>A p.S617* | Nonsense Mutation (SNP) | VAF 88/270 reads (33%) | called by muse, mutect2, varscan2
- GREB1L | c.4741G>A p.A1581T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); called by muse, mutect2
- HERPUD1 | c.617_618del p.V206Gfs*16 | Frame Shift Del (DEL) | VAF 72/182 reads (40%) | called by pindel, varscan2
- IGHV2-70 | c.103_105dup p.Q35dup | In Frame Ins (INS) | VAF 24/50 reads (48%) | called by pindel, varscan2
- IGHV2-70D | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- IL3RA | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.193); called by muse, mutect2
- IRAK1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITK | c.713A>C p.E238A | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LRRC4 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- LYZL1 | c.515G>A p.W172* (on ENST00000375500; = p.W126* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- MAGI3 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NONO | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPAT | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NSD3 | c.3241G>A p.V1081I | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PDSS1 | c.1108-1G>C p.X370_splice | Splice Site (SNP) | VAF 100/200 reads (50%) | called by muse, mutect2, varscan2
- PDXDC1 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PLEKHG7 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 95/217 reads (44%) | called by muse, mutect2, varscan2
- SMS | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SP140 | c.2362-1G>T p.X788_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- STK17A | c.175_204del p.Y59_G68del | In Frame Del (DEL) | VAF 20/38 reads (53%) | called by mutect2, varscan2
- UBR5 | c.7962G>A p.M2654I | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- USH2A | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- WNT8A | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF727 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BNIP2 | c.264G>A p.P88= | Silent (SNP) | VAF 91/281 reads (32%) | catalogued as rs774065595; called by muse, mutect2, varscan2
- DKC1 | c.756A>G p.G252= | Silent (SNP) | VAF 49/139 reads (35%) | called by muse, mutect2, varscan2
- DUSP2 | c.414C>T p.C138= | Silent (SNP) | VAF 74/134 reads (55%) | catalogued as COSV56619333; called by muse, mutect2, varscan2
- DUSP2 | c.252G>A p.E84= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs768266724, COSV56619478; called by muse, varscan2
- FREM1 | c.5736G>T p.R1912= | Silent (SNP) | VAF 59/301 reads (20%) | called by muse, mutect2, varscan2
- GK | c.522T>A p.L174= | Silent (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2
- IGHV2-70D | c.156A>T p.G52= | Silent (SNP) | VAF 86/242 reads (36%) | called by muse, varscan2
- KIF1B | c.3387C>A p.I1129= (on ENST00000377086 / NM_001365952.1; = p.I1083= on NM_015074.3) | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as COSV99823906; called by muse, mutect2
- LINGO3 | c.1614C>T p.F538= | Silent (SNP) | VAF 89/290 reads (31%) | called by muse, mutect2, varscan2
- MYRF | c.1302C>T p.H434= (on ENST00000278836 / NM_001127392.3; = p.H425= on NM_013279.4) | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs370594037; called by muse, mutect2, varscan2
- PCDHAC1 | c.1362T>A p.V454= | Silent (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1335C>T p.D445= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- PNMA8A | c.711T>G p.A237= | Silent (SNP) | VAF 46/185 reads (25%) | called by muse, mutect2, varscan2
- PRDM15 | c.1320C>T p.C440= | Silent (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- SHC4 | c.1563G>A p.L521= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- USP35 | c.193C>T p.L65= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs538602309; called by muse, varscan2
- ZFAT | c.2589G>A p.E863= | Silent (SNP) | VAF 66/174 reads (38%) | called by muse, mutect2, varscan2
- ABI3BP | c.-14G>A | 5'UTR (SNP) | VAF 57/198 reads (29%) | called by muse, mutect2, varscan2
- ANKFY1 | c.2240+62T>A | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as rs905756985; called by muse, mutect2, varscan2
- ARNTL2 | chr12:27422929 T>C | 3'Flank (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- ASPG | c.192-73C>T | Intron (SNP) | VAF 43/63 reads (68%) | catalogued as rs753062458; called by muse, mutect2, varscan2
- ATP1B4 | c.*2161T>C | 3'UTR (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.1038+119C>G | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as rs1401701760; called by muse, mutect2
- ATRNL1 | c.3795+48090G>A | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- CAP1 | c.*252A>C | 3'UTR (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- CBLN4 | c.-1149G>A | 5'UTR (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- CCNJL | n.42A>G | RNA (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- CD82 | c.262-42C>T | Intron (SNP) | VAF 31/65 reads (48%) | catalogued as rs761902871; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33691A>G | Intron (SNP) | VAF 35/50 reads (70%) | called by muse, mutect2, varscan2
- CLSTN1 | c.*925C>T | 3'UTR (SNP) | VAF 88/161 reads (55%) | called by muse, mutect2, varscan2
- CNOT3 | c.-50-1439G>A | Intron (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- COL13A1 | c.-240C>T | 5'UTR (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.*92C>T | 3'UTR (SNP) | VAF 131/357 reads (37%) | catalogued as rs1281991658; called by muse, mutect2, varscan2
- CTNND1 | c.*2769G>C | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- DTL | c.*1559del | 3'UTR (DEL) | VAF 52/221 reads (24%) | called by mutect2, pindel, varscan2
- EHF | c.*1852G>T | 3'UTR (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- EIF4E1B | c.297-87G>A | Intron (SNP) | VAF 20/52 reads (38%) | catalogued as rs535773603; called by muse, varscan2
- EPHA8 | c.*1199C>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- ERLIN2 | chr8:37736249 ins A | 5'Flank (INS) | VAF 38/80 reads (48%) | catalogued as rs1003583312; called by mutect2, varscan2
- FAM169A | c.*1725A>G | 3'UTR (SNP) | VAF 37/123 reads (30%) | catalogued as rs1010562892; called by muse, mutect2, varscan2
- FANCD2 | c.696-67C>T | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV55049264; called by muse, mutect2, varscan2
- FMO5 | c.-38+9C>A | Intron (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- GSR | c.*1G>A | 3'UTR (SNP) | VAF 99/207 reads (48%) | catalogued as rs915133836; called by muse, mutect2, varscan2
- IGF2BP3 | c.*24A>G | 3'UTR (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*4222_*4223insA | 3'UTR (INS) | VAF 28/97 reads (29%) | catalogued as COSV99289058; called by pindel, varscan2
- IGFN1 | c.*30C>A | 3'UTR (SNP) | VAF 136/608 reads (22%) | catalogued as COSV99812846; called by muse, mutect2, varscan2
- IGHV6-1 | c.-37T>A | 5'UTR (SNP) | VAF 16/16 reads (100%) | catalogued as rs373665496; called by muse, mutect2, varscan2
- KIF13A | c.4581+306G>A | Intron (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- LMAN1 | c.*1233T>G | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- LRCH2 | c.*1296T>A | 3'UTR (SNP) | VAF 47/79 reads (59%) | catalogued as rs1246057069; called by muse, mutect2, varscan2
- MAP2K3 | c.166-23G>A | Intron (SNP) | VAF 38/226 reads (17%) | called by muse, mutect2
- MIER3 | c.*1336G>C | 3'UTR (SNP) | VAF 62/159 reads (39%) | called by muse, mutect2, varscan2
- NPY | c.1-132G>T | Intron (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- NR2F2 | c.-470G>A | 5'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, varscan2
- NR5A2 | c.1110+9232G>A | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, varscan2
- OBSCN | c.11659+4900C>A | Intron (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- OR52L2P | n.561C>A | RNA (SNP) | VAF 73/165 reads (44%) | called by muse, mutect2, varscan2
- PCDH7 | c.*1137T>C | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PDS5B | c.*275dup | 3'UTR (INS) | VAF 10/14 reads (71%) | catalogued as rs200496593; called by mutect2, varscan2
- PIK3CB | c.*1C>T | 3'UTR (SNP) | VAF 173/560 reads (31%) | catalogued as rs756330302; called by muse, mutect2, varscan2
- PSCA | c.*235C>T | 3'UTR (SNP) | VAF 132/298 reads (44%) | catalogued as rs1291589002; called by muse, mutect2
- RAC2 | c.-58del | 5'UTR (DEL) | VAF 47/125 reads (38%) | called by mutect2, pindel, varscan2
- RACK1 | c.429+131G>A | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- RAD18 | c.*2025C>T | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- RNF19A | c.*488T>G | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- RSBN1 | c.*4110_*4114del | 3'UTR (DEL) | VAF 9/22 reads (41%) | catalogued as rs772042986; called by mutect2, pindel, varscan2
- RTEL1 | c.959-15C>T | Intron (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- SCML4 | c.488-65C>T | Intron (SNP) | VAF 32/32 reads (100%) | catalogued as rs531225110; called by muse, mutect2, varscan2
- SCN4B | c.*2482del | 3'UTR (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- SLC5A5 | c.*16C>T | 3'UTR (SNP) | VAF 20/86 reads (23%) | catalogued as rs367906323; called by muse, mutect2, varscan2
- SPRED2 | c.27-21745A>G | Intron (SNP) | VAF 80/174 reads (46%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76563547 C>T | 3'Flank (SNP) | VAF 176/428 reads (41%) | called by muse, mutect2, varscan2
- TFR2 | c.966+56G>T | Intron (SNP) | VAF 67/229 reads (29%) | called by muse, mutect2, varscan2
- TOX2 | c.*533A>G | 3'UTR (SNP) | VAF 27/52 reads (52%) | catalogued as rs1004443772; called by muse, mutect2, varscan2
- TRIM36 | c.*171G>A | 3'UTR (SNP) | VAF 41/114 reads (36%) | called by muse, mutect2, varscan2
- UBB | c.*124A>G | 3'UTR (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- VCPIP1 | c.*314C>A | 3'UTR (SNP) | VAF 54/88 reads (61%) | catalogued as COSV100125632; called by muse, mutect2, varscan2
- VGLL3 | c.*8873A>T | 3'UTR (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- ZNF502 | c.*1226C>A | 3'UTR (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
